Gene-level copy-number profile of tumor specimen TCGA-61-2008-02A from TCGA case TCGA-61-2008, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 40.5 years (14,791 days).
Specimen TCGA-61-2008-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ac13ba9d-e8f3-44f1-9a72-cf4bbb9aa1a7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2008-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/5760fcce-232a-401b-97f5-19fa44d035d1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 2,916; copy number 2: 17,007; copy number 3: 22,493; copy number 4: 12,226; copy number 5: 1,849; copy number 6: 1,695; copy number 7: 1,448; copy number 8: 76.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,925,983–29,929,232, 2 genes: HCG4B, HLA-K.
- chr16:55,760,566–55,793,960, 1 gene (within-gene range 0–3): CES1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,524 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–7,769,706, 261 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:237,042,184–237,833,988, 1 gene, copy number 7 (within-gene range 6–7): RYR2.
- chr1:237,471,119–248,919,946, 272 genes, copy number 7–8 (broad region; genes not listed).
- chr3:172,425,850–183,463,201, 167 genes, copy number 7 (broad region; genes not listed).
- chr3:197,889,077–198,222,513, 13 genes, copy number 8: IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr5:10,971,836–17,502,363, 74 genes, copy number 7 (broad region; genes not listed).
- chr5:24,449,351–26,484,711, 28 genes, copy number 8: Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr8:105,546,089–145,066,685, 584 genes, copy number 7 (broad region; genes not listed).
- chr20:7,069,614–13,169,103, 72 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:47,318,502–49,484,297, 52 genes, copy number 7: AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1.

Autosomal genes at a single copy (total copy number 1): 1,964. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
